Gene-level copy-number profile of tumor specimen CDDP-A8B9-TTP1-D from CDDP_EAGLE case CDDP-A8B9, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 69 years.
Specimen CDDP-A8B9-TTP1-D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5f18d1f5-5bb5-4d88-bc34-616f4372749f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-A8B9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/ac276bd1-d5b8-43d6-aaf7-350221cabea2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 11; copy number 1: 5,839; copy number 2: 51,712; copy number 3: 772; copy number 4: 59; copy number 5: 7.

Homozygous deletions (total copy number 0; autosomes only): 11 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:89,319,625–89,600,680, 3 genes: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr12:60,341,824–60,341,941, 1 gene: Y_RNA.
- chr17:27,623,364–27,640,777, 1 gene (within-gene range 0–2): AC015688.4.
- chr17:27,629,798–27,649,560, 1 gene: LGALS9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:29,887,294–29,929,232, 7 genes, copy number 5: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.

Autosomal genes at a single copy (total copy number 1): 5,839. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
